Somatic mutation profile of tumor specimen TCGA-85-8580-01A (aliquot TCGA-85-8580-01A-31D-2395-08) from TCGA case TCGA-85-8580, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 52.8 years (19,301 days).
Specimen TCGA-85-8580-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9d343755-e869-48a6-ab7b-4c2c97f9657e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-85-8580-10A (Blood Derived Normal), aliquot TCGA-85-8580-10A-01D-2395-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5d1ce5f5-fbc7-4d65-a4ed-e7c55f0281c4

The open-access MAF lists 301 somatic variants for this specimen: 219 protein-altering or splice-affecting, 73 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 186, Silent 73, Nonsense Mutation 15, Frame Shift Del 8, RNA 6, Splice Site 5, Frame Shift Ins 3, Intron 2, Splice Region 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RB1 | c.1666C>T p.R556* | Nonsense Mutation (SNP) | VAF 8/42 reads (19%) | catalogued as rs121913304, CM942039, COSV57296489; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.747G>T p.R249S | Missense Mutation (SNP) | VAF 25/99 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs28934571, COSV52661594, COSV52668882, COSV52827572; ClinVar: pathogenic / likely pathogenic / conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- A4GNT | c.441C>A p.H147Q | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as COSV99367773; called by muse, mutect2, varscan2
- ABCA13 | c.1666A>G p.I556V | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0.228); catalogued as COSV101329996; called by muse, mutect2, varscan2
- ABCB7 | c.1496A>G p.K499R (on ENST00000373394 / NM_001271696.3; = p.K500R on NM_004299.6) | Missense Mutation (SNP) | VAF 29/196 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.168); catalogued as COSV99504159; called by muse, mutect2, varscan2
- ABCC11 | c.2765G>T p.C922F | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.89); catalogued as COSV100750658; called by muse, varscan2
- ACMSD | c.580G>A p.G194R | Missense Mutation (SNP) | VAF 33/165 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99298930; called by muse, mutect2, varscan2
- ACRBP | c.914A>T p.N305I | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as COSV99976041; called by muse, mutect2, varscan2
- ADAM30 | c.2327A>G p.E776G | Missense Mutation (SNP) | VAF 20/266 reads (8%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as COSV101023808; called by muse, mutect2
- ADAMTS4 | c.692C>T p.A231V | Missense Mutation (SNP) | VAF 79/438 reads (18%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs1175006490, COSV100917409; called by muse, mutect2, varscan2
- AGRP | c.100C>A p.P34T | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.272); catalogued as COSV99341090; called by muse, mutect2
- AHNAK | c.16038A>T p.K5346N | Missense Mutation (SNP) | VAF 40/187 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV99946649; called by muse, mutect2, varscan2
- AHNAK | c.1791A>T p.K597N | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.79); catalogued as COSV99946651; called by muse, mutect2, varscan2
- ANK1 | c.5074G>T p.V1692L | Missense Mutation (SNP) | VAF 32/170 reads (19%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.027); catalogued as COSV99224711; called by muse, mutect2, varscan2
- ANKEF1 | c.1447G>T p.V483F | Missense Mutation (SNP) | VAF 32/143 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV101001002; called by muse, mutect2, varscan2
- ARL5B | c.206G>A p.G69D | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.537); catalogued as COSV101040274, COSV66011274; called by muse, mutect2, varscan2
- ATP6V0A2 | c.668A>G p.Y223C | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs761908912, COSV100376936; called by muse, mutect2, varscan2
- B3GNT7 | c.442G>A p.D148N | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1447765254, COSV99805878; called by muse, mutect2, varscan2
- BARX1 | c.589T>A p.W197R | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99560967; called by muse, mutect2, varscan2
- BCR | c.955C>T p.R319W | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.723); catalogued as COSV100006318, COSV59928460; called by muse, mutect2, varscan2
- C1QTNF4 | c.245C>T p.A82V | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100209246; called by muse, varscan2
- CBFA2T2 | c.1106T>A p.M369K | Missense Mutation (SNP) | VAF 26/156 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as COSV100656245; called by muse, mutect2, varscan2
- CBFA2T2 | c.1107G>T p.M369I | Missense Mutation (SNP) | VAF 27/156 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.062); catalogued as rs771803713, COSV100656246; called by muse, mutect2, varscan2
- CCNL1 | c.452A>C p.N151T | Missense Mutation (SNP) | VAF 11/115 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99904164; called by muse, mutect2, varscan2
- CCPG1 | c.1409G>C p.G470A | Missense Mutation (SNP) | VAF 48/378 reads (13%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.975); catalogued as COSV99380208; called by muse, mutect2, varscan2
- CD209 | c.106G>T p.G36W | Missense Mutation (SNP) | VAF 44/624 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99213841; called by muse, mutect2
- CD40 | c.655G>T p.A219S | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as COSV100953817; called by muse, mutect2, varscan2
- CDK12 | c.1283C>G p.P428R | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.029); catalogued as COSV101420408; called by muse, mutect2, varscan2
- CFAP44 | c.1075C>T p.R359* | Nonsense Mutation (SNP) | VAF 45/425 reads (11%) | catalogued as rs763345969, COSV55612387; called by muse, mutect2, varscan2
- CFLAR | c.1021A>G p.M341V | Missense Mutation (SNP) | VAF 30/140 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.029); catalogued as rs781326383, COSV100009207; called by muse, mutect2, varscan2
- CKMT2 | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.511); catalogued as rs1216063009, COSV54173456; called by muse, mutect2, varscan2
- COL20A1 | c.3445C>A p.P1149T | Missense Mutation (SNP) | VAF 25/148 reads (17%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.547); catalogued as COSV100490232; called by muse, mutect2, varscan2
- COL22A1 | c.278G>T p.G93V | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); catalogued as COSV100277500; called by muse, mutect2, varscan2
- COL4A4 | c.1220C>A p.P407H | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV100306538; called by muse, mutect2
- CPS1 | c.2203G>T p.A735S | Missense Mutation (SNP) | VAF 26/157 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV99242620; called by muse, mutect2, varscan2
- CSHL1 | c.324C>G p.H108Q (on ENST00000309894 / NM_022581.3; = p.H14Q on NM_001318.4) | Missense Mutation (SNP) | VAF 6/99 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.026); catalogued as COSV99367898; called by muse, mutect2
- CSMD3 | c.4420G>T p.G1474C (on ENST00000297405 / NM_001363185.1; = p.G1370C on NM_052900.3) | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV52321900, COSV99830280; called by muse, mutect2, varscan2
- DCAF12L1 | c.234C>A p.Y78* | Nonsense Mutation (SNP) | VAF 46/148 reads (31%) | catalogued as COSV100948202, COSV64421700; called by muse, mutect2, varscan2
- DCC | c.2613G>T p.K871N | Missense Mutation (SNP) | VAF 37/171 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100499098; called by muse, mutect2, varscan2
- DLGAP1 | c.616G>A p.D206N | Missense Mutation (SNP) | VAF 81/382 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as rs1318841482, COSV100229292; called by muse, mutect2, varscan2
- DLST | c.631G>T p.A211S | Missense Mutation (SNP) | VAF 27/113 reads (24%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV99471890; called by muse, mutect2, varscan2
- DNAH5 | c.8976G>T p.M2992I | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.05); catalogued as COSV54247879, COSV99447701; called by muse, mutect2
- DNAH5 | c.1176G>T p.K392N | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV54251612, COSV99447704; called by muse, mutect2, varscan2
- DSC2 | c.2629G>T p.E877* | Nonsense Mutation (SNP) | VAF 28/112 reads (25%) | catalogued as COSV99199584, COSV99199927; called by muse, mutect2, varscan2
- DUOX2 | c.2073G>T p.Q691H | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as COSV101199675; called by muse, mutect2, varscan2
- ECPAS | c.4541G>T p.G1514V | Missense Mutation (SNP) | VAF 13/132 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as COSV99397879; called by muse, mutect2
- EEF1A2 | c.1079T>C p.V360A | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.101); catalogued as COSV99419242; called by muse, mutect2, varscan2
- EGR1 | c.1201T>G p.C401G | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99525382; called by muse, mutect2, varscan2
- ELOVL5 | c.134T>G p.I45S | Missense Mutation (SNP) | VAF 33/150 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.038); catalogued as COSV100439650; called by muse, mutect2, varscan2
- EMILIN1 | c.251C>A p.P84H | Missense Mutation (SNP) | VAF 28/182 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100980195; called by muse, varscan2
- EPB41L3 | c.3201G>T p.M1067I | Missense Mutation (SNP) | VAF 25/162 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100548604; called by muse, mutect2, varscan2
- ERV3-1 | c.1237del p.A413Hfs*36 | Frame Shift Del (DEL) | VAF 17/82 reads (21%) | catalogued as COSV51428201; called by mutect2, pindel, varscan2
- ESRRB | c.163G>T p.G55C | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as rs373173218; called by muse, mutect2, varscan2
- FAHD2A | c.211G>T p.E71* | Nonsense Mutation (SNP) | VAF 16/93 reads (17%) | catalogued as COSV99271944; called by muse, mutect2, varscan2
- FAM155A | c.1259G>T p.C420F | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as COSV101027441; called by muse, mutect2, varscan2
- FAM83B | c.1803G>T p.K601N | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV100174275; called by mutect2, varscan2
- FAT4 | c.13241A>G p.D4414G | Missense Mutation (SNP) | VAF 48/242 reads (20%) | SIFT tolerated (0.64); PolyPhen probably damaging (0.941); catalogued as rs769002810, COSV100628058; called by muse, mutect2, varscan2
- FER1L6 | c.402C>A p.F134L | Missense Mutation (SNP) | VAF 19/138 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.046); catalogued as COSV101205698; called by muse, mutect2, varscan2
- FHDC1 | c.2064G>T p.Q688H | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.123); catalogued as COSV99471164; called by muse, mutect2, varscan2
- FKBP6 | c.770T>A p.F257Y | Missense Mutation (SNP) | VAF 31/61 reads (51%) | SIFT tolerated (0.11); PolyPhen benign (0.365); catalogued as COSV99333883; called by muse, mutect2, varscan2
- FSTL1 | c.136G>T p.E46* | Nonsense Mutation (SNP) | VAF 87/239 reads (36%) | catalogued as COSV99820601; called by muse, mutect2, varscan2
- FXYD6 | c.173-1G>T p.X58_splice | Splice Site (SNP) | VAF 12/91 reads (13%) | catalogued as COSV99502447; called by muse, mutect2, varscan2
- G6PC | c.989G>T p.S330I | Missense Mutation (SNP) | VAF 57/300 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99520719; called by muse, mutect2, varscan2
- GHRHR | c.946G>T p.G316C | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.937); catalogued as COSV100396547; called by muse, mutect2, varscan2
- GJD2 | c.824T>C p.L275P | Missense Mutation (SNP) | VAF 19/141 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99290653; called by muse, mutect2, varscan2
- GLRB | c.1367A>T p.N456I | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.188); catalogued as COSV100029611; called by muse, mutect2, varscan2
- GRIK3 | c.244G>T p.D82Y | Missense Mutation (SNP) | VAF 79/240 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100901715; called by muse, mutect2, varscan2
- GRIK3 | c.17G>T p.R6L | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as COSV66136940; called by muse, mutect2
- GRIN3A | c.463G>A p.E155K | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.491); catalogued as COSV100701436; called by muse, mutect2
- HDGF | c.631C>T p.P211S | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as COSV100625680; called by muse, mutect2, varscan2
- HECTD4 | c.12454G>T p.E4152* | Nonsense Mutation (SNP) | VAF 14/143 reads (10%) | catalogued as COSV101107158; called by muse, mutect2, varscan2
- HIVEP1 | c.1366C>T p.H456Y | Missense Mutation (SNP) | VAF 24/127 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101044711, COSV101045022; called by muse, mutect2, varscan2
- HOOK2 | c.352G>T p.V118L | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as COSV99317464; called by muse, mutect2, varscan2
- HSPA8 | c.559A>G p.K187E | Missense Mutation (SNP) | VAF 16/167 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.785); catalogued as COSV99914309; called by muse, mutect2
- HYAL4 | c.278A>G p.N93S | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.062); catalogued as rs779208724, COSV99772165; called by muse, mutect2, varscan2
- IFT57 | c.1280G>T p.G427V | Missense Mutation (SNP) | VAF 17/156 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.134); catalogued as COSV52708140, COSV99197340; called by muse, mutect2, varscan2
- INTS12 | c.98C>T p.A33V | Missense Mutation (SNP) | VAF 15/167 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.193); catalogued as COSV100415786, COSV60862376; called by muse, mutect2
- ITGA8 | c.1795C>A p.P599T | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100959081; called by muse, mutect2, varscan2
- ITPKB | c.2131T>G p.F711V | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.186); catalogued as COSV99684086; called by muse, mutect2, varscan2
- JCAD | c.922G>A p.A308T | Missense Mutation (SNP) | VAF 41/205 reads (20%) | SIFT tolerated (0.57); PolyPhen benign (0.167); catalogued as COSV100948250; called by muse, mutect2, varscan2
- KANSL1 | c.1658A>C p.Q553P | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV99294310; called by muse, mutect2
- KCNC1 | c.1114C>G p.Q372E | Missense Mutation (SNP) | VAF 21/125 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.044); catalogued as COSV99789026; called by muse, mutect2, varscan2
- KCNH8 | c.2083G>A p.E695K | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.071); catalogued as rs866881381, COSV100109285; called by muse, mutect2, varscan2
- KIR2DL3 | c.320C>A p.S107Y | Missense Mutation (SNP) | VAF 103/925 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.225); catalogued as COSV100668164; called by muse, mutect2, varscan2
- KLHL10 | c.1452+1G>A p.X484_splice | Splice Site (SNP) | VAF 14/94 reads (15%) | catalogued as COSV99509469; called by muse, mutect2, varscan2
- KPTN | c.734T>A p.L245Q | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV100583405; called by muse, mutect2
- LRP12 | c.239T>C p.I80T | Missense Mutation (SNP) | VAF 37/170 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99407487; called by muse, mutect2, varscan2
- LRP1B | c.7289G>T p.R2430L | Missense Mutation (SNP) | VAF 24/135 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV67206126, COSV67212753; called by muse, mutect2, varscan2
- MAGIX | c.388C>T p.R130C | Missense Mutation (SNP) | VAF 12/233 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1557097308, COSV66256605; called by muse, mutect2
- MAMDC4 | c.28G>A p.A10T | Missense Mutation (SNP) | VAF 23/251 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs375692420; called by muse, mutect2
- MEP1A | c.569A>G p.N190S | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs757969989, COSV100042546; called by muse, mutect2, varscan2
- MEP1A | c.1726C>A p.L576M | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); catalogued as COSV100042547; called by muse, mutect2, varscan2
- MORC1 | c.317G>T p.G106V | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99225631; called by muse, mutect2, varscan2
- MORN3 | c.372C>A p.S124R | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as rs782815065, COSV100804463; called by muse, mutect2, varscan2
- MPP7 | c.233A>T p.D78V | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.92); catalogued as COSV100517204; called by muse, mutect2
- MSN | c.559G>C p.A187P | Missense Mutation (SNP) | VAF 16/233 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100814159; called by muse, mutect2
- MTRR | c.1309G>T p.A437S (on ENST00000264668; = p.A410S on NM_002454.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/141 reads (23%) | SIFT tolerated (0.43); PolyPhen benign (0.099); catalogued as COSV52946500, COSV99241534; called by muse, mutect2, varscan2
- MUC16 | c.31352G>A p.G10451D | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.042); catalogued as COSV67499557; called by muse, mutect2, varscan2
- MUC17 | c.11353A>G p.M3785V | Missense Mutation (SNP) | VAF 56/159 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.143); catalogued as COSV100072579; called by muse, mutect2, varscan2
- MUC5B | c.5908A>G p.S1970G | Missense Mutation (SNP) | VAF 78/268 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV101500210; called by muse, varscan2
- MYH2 | c.2894T>A p.L965Q | Missense Mutation (SNP) | VAF 38/306 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99819746; called by muse, mutect2, varscan2
- MYH4 | c.3230A>G p.K1077R | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.11); catalogued as COSV55122465, COSV99700856; called by muse, mutect2, varscan2
- MYH8 | c.2438C>A p.A813E | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.236); catalogued as COSV101238349; called by muse, mutect2, varscan2
- MYO1B | c.286C>G p.R96G | Missense Mutation (SNP) | VAF 48/328 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV100268889, COSV58435175; called by muse, mutect2, varscan2
- MYO1F | c.649del p.A217Pfs*12 | Frame Shift Del (DEL) | VAF 31/169 reads (18%) | catalogued as CM090126; called by mutect2, pindel, varscan2
- MYPN | c.1136A>G p.Q379R | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT tolerated (0.44); PolyPhen benign (0.15); catalogued as COSV62740889; called by mutect2, varscan2
- NLRP13 | c.1348C>A p.Q450K | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.031); catalogued as COSV100738131, COSV61620365; called by muse, mutect2
- NPC1L1 | c.681G>T p.Q227H | Missense Mutation (SNP) | VAF 44/182 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.023); catalogued as COSV99204274; called by muse, mutect2, varscan2
- NR0B1 | c.1169-2A>T p.X390_splice | Splice Site (SNP) | VAF 4/59 reads (7%) | catalogued as COSV100973486; called by muse, mutect2
- NUP210 | c.2140G>T p.A714S | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as COSV99595927; called by muse, mutect2, varscan2
- NUP98 | c.784A>G p.S262G | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV61433649; called by muse, mutect2, varscan2
- NYAP2 | c.8C>A p.S3Y | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.045); catalogued as COSV55998674, COSV99796229; called by muse, varscan2
- OR13D1 | c.89T>C p.L30P | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.087); catalogued as COSV100598669; called by mutect2, varscan2
- OR1S1 | c.518C>A p.T173N | Missense Mutation (SNP) | VAF 60/298 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV100515333; called by muse, mutect2, varscan2
- OR51Q1 | c.217C>A p.L73M | Missense Mutation (SNP) | VAF 47/211 reads (22%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); catalogued as COSV56178825; called by muse, mutect2, varscan2
- OR5B2 | c.115G>T p.G39W | Missense Mutation (SNP) | VAF 34/182 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.799); catalogued as COSV100222830; called by muse, mutect2, varscan2
- OR9Q1 | c.541C>T p.L181F | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.452); catalogued as COSV100109699; called by muse, mutect2, varscan2
- OTOF | c.1537C>T p.H513Y | Missense Mutation (SNP) | VAF 15/133 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as COSV99717147; called by muse, mutect2, varscan2
- P2RY8 | c.22G>T p.G8C | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.387); catalogued as COSV67178613; called by muse, mutect2
- PAICS | c.539G>A p.W180* | Nonsense Mutation (SNP) | VAF 8/21 reads (38%) | catalogued as COSV99947733; called by muse, mutect2, varscan2
- PCDH11X | c.3746T>C p.L1249S | Missense Mutation (SNP) | VAF 14/311 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.038); catalogued as COSV100010546; called by muse, mutect2
- PCDH15 | c.4826G>A p.S1609N | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated, low confidence (0.07); catalogued as rs1224400863, COSV100903675; called by muse, mutect2, varscan2
- PCDH9 | c.2122G>T p.G708* | Nonsense Mutation (SNP) | VAF 25/110 reads (23%) | catalogued as COSV100119555; called by muse, mutect2, varscan2
- PCDHGB1 | c.1133T>C p.V378A | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV99534888; called by muse, mutect2, varscan2
- PDE1C | c.1530G>A p.W510* | Nonsense Mutation (SNP) | VAF 13/224 reads (6%) | catalogued as COSV100371959; called by muse, mutect2
- PDYN | c.272C>A p.P91H | Missense Mutation (SNP) | VAF 33/155 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.428); catalogued as COSV99452895; called by muse, mutect2, varscan2
- PIEZO2 | c.6799G>T p.V2267L | Missense Mutation (SNP) | VAF 27/148 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as COSV99554792; called by muse, mutect2, varscan2
- PIK3R2 | c.1085A>T p.Q362L | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.551); catalogued as COSV99717325; called by muse, mutect2, varscan2
- PIK3R5 | c.1694A>G p.H565R | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs1182750862, COSV99353128; called by muse, mutect2
- POGLUT2 | c.389G>C p.G130A | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.658); catalogued as COSV101050780; called by muse, mutect2, varscan2
- POLR1B | c.1825G>T p.G609* | Nonsense Mutation (SNP) | VAF 21/151 reads (14%) | catalogued as rs1369476555, COSV99637465; called by muse, mutect2, varscan2
- PPFIA2 | c.2451C>A p.S817R | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV100332598; called by muse, mutect2, varscan2
- PROX1 | c.686A>G p.K229R | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.433); catalogued as COSV99799030; called by muse, mutect2, varscan2
- PTGER4 | c.782G>T p.R261L | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.491); catalogued as COSV100201495; called by muse, mutect2
- RDH10 | c.383C>T p.T128M | Missense Mutation (SNP) | VAF 12/196 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.353); catalogued as rs1382657995, COSV99536241; called by muse, mutect2
- RIMS2 | c.2653+1G>C p.X885_splice (on ENST00000666250 / NM_001348490.2; = p.X693_splice on NM_014677.5 and 7 other RefSeq transcripts) | Splice Site (SNP) | VAF 12/64 reads (19%) | catalogued as COSV99165833; called by muse, mutect2, varscan2
- RNF130 | c.1033G>T p.D345Y | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99992613; called by muse, mutect2, varscan2
- RNF213 | c.12688G>T p.A4230S | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV100300177; called by muse, mutect2, varscan2
- RNF214 | c.305del p.G102Afs*8 | Frame Shift Del (DEL) | VAF 49/186 reads (26%) | catalogued as COSV56121111; called by mutect2, pindel, varscan2
- RO60 | c.467A>G p.Y156C | Missense Mutation (SNP) | VAF 28/145 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100814347; called by muse, mutect2, varscan2
- RPL10L | c.10C>A p.R4S | Missense Mutation (SNP) | VAF 28/164 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.166); catalogued as COSV53558692; called by muse, mutect2, varscan2
- RRM2B | c.358G>T p.A120S | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.947); catalogued as COSV99060434, COSV99310030; called by muse, mutect2, varscan2
- RUFY2 | c.928-1G>T p.X310_splice | Splice Site (SNP) | VAF 13/62 reads (21%) | catalogued as COSV101175808; called by muse, mutect2, varscan2
- RYR2 | c.8648C>A p.A2883D | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.775); catalogued as COSV63715964; called by muse, mutect2
- SCARA5 | c.332G>T p.R111L | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0.05); PolyPhen benign (0.189); catalogued as COSV100107774; called by muse, mutect2, varscan2
- SCN8A | c.1281A>C p.Q427H | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.365); catalogued as COSV100633601; called by muse, mutect2
- SCNM1 | c.371A>G p.Y124C | Missense Mutation (SNP) | VAF 71/438 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763985521, COSV54862044; called by muse, mutect2, varscan2
- SEMA4D | c.1663G>C p.D555H | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.498); catalogued as COSV100358152; called by muse, mutect2, varscan2
- SENP7 | c.1118G>A p.S373N | Missense Mutation (SNP) | VAF 21/162 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.145); catalogued as COSV100052811; called by muse, mutect2, varscan2
- SERPINA9 | c.398G>C p.G133A | Missense Mutation (SNP) | VAF 49/180 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100098189; called by muse, mutect2, varscan2
- SI | c.3419del p.P1140Lfs*44 | Frame Shift Del (DEL) | VAF 12/113 reads (11%) | catalogued as rs35558903; called by mutect2, pindel, varscan2
- SIDT2 | c.1891A>T p.T631S | Missense Mutation (SNP) | VAF 45/141 reads (32%) | SIFT tolerated (0.6); PolyPhen benign (0.009); catalogued as rs1197793532, COSV99637463; called by muse, mutect2, varscan2
- SIRPD | c.283C>A p.P95T | Missense Mutation (SNP) | VAF 26/127 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.11); catalogued as COSV101064882; called by muse, mutect2, varscan2
- SLC17A9 | c.909G>A p.Q303= | Splice Region (SNP) | VAF 62/340 reads (18%) | catalogued as COSV100947787; called by muse, mutect2, varscan2
- SLC1A4 | c.582T>G p.D194E | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV99308890; called by muse, mutect2, varscan2
- SLC35F6 | c.85G>T p.D29Y | Missense Mutation (SNP) | VAF 20/135 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100733636; called by muse, mutect2, varscan2
- SLC44A2 | c.352G>A p.D118N | Missense Mutation (SNP) | VAF 14/313 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV100213097; called by muse, mutect2
- SMPD1 | c.1053G>A p.W351* | Nonsense Mutation (SNP) | VAF 21/76 reads (28%) | catalogued as COSV100192576; called by muse, mutect2, varscan2
- SNRPN | c.217C>T p.R73C | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1298673972, COSV57594900; called by muse, mutect2, varscan2
- SOS2 | c.1285G>A p.G429R | Missense Mutation (SNP) | VAF 44/169 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.113); catalogued as COSV99365775; called by muse, mutect2, varscan2
- SPSB2 | c.313G>T p.V105L | Missense Mutation (SNP) | VAF 19/140 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.13); catalogued as rs782359822, COSV99222837; called by muse, mutect2, varscan2
- STRC | c.4243G>T p.E1415* | Nonsense Mutation (SNP) | VAF 12/64 reads (19%) | catalogued as COSV100294520; called by muse, mutect2, varscan2
- STX18 | c.470T>G p.V157G | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV100086104; called by muse, mutect2, varscan2
- STX1A | c.658G>T p.A220S | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.848); catalogued as COSV56094385, COSV99736455; called by muse, mutect2, varscan2
- TESPA1 | c.1400G>A p.S467N (on ENST00000316577 / NM_001098815.3; = p.S329N on NM_014796.2 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 59/310 reads (19%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as COSV100345099; called by muse, mutect2, varscan2
- TGIF2LX | c.229T>C p.Y77H | Missense Mutation (SNP) | VAF 46/219 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.397); catalogued as COSV99383258; called by muse, mutect2, varscan2
- TLN2 | c.3379G>T p.A1127S | Missense Mutation (SNP) | VAF 7/98 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.569); catalogued as COSV100168595; called by muse, mutect2
- TMOD2 | c.919A>T p.M307L | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.025); catalogued as COSV99987694; called by muse, mutect2, varscan2
- TMPRSS11B | c.531C>A p.N177K | Missense Mutation (SNP) | VAF 32/116 reads (28%) | SIFT tolerated (0.47); PolyPhen benign (0.006); catalogued as COSV100219301; called by muse, mutect2, varscan2
- TNFRSF11A | c.1086C>A p.F362L | Missense Mutation (SNP) | VAF 35/112 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99500118; called by muse, mutect2, varscan2
- TNR | c.3245G>T p.R1082L | Missense Mutation (SNP) | VAF 26/137 reads (19%) | SIFT tolerated (0.75); PolyPhen probably damaging (0.999); catalogued as rs745921585, COSV54876456, COSV99688777; called by muse, mutect2, varscan2
- TRMT2A | c.404A>C p.K135T | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99349906; called by muse, mutect2, varscan2
- TRPM3 | c.409C>A p.P137T (on ENST00000357533 / NM_001366142.2; = p.P106T on NM_001007471.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/183 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV62467090; called by muse, mutect2, varscan2
- TTN | c.53381T>C p.I17794T (on ENST00000591111; = p.I10370T on NM_003319.4) | Missense Mutation (SNP) | VAF 31/144 reads (22%) | PolyPhen possibly damaging (0.503); catalogued as rs935570365, COSV100603556; called by muse, mutect2, varscan2
- TTN | c.9173T>C p.I3058T (on ENST00000591111; = p.I3012T on NM_003319.4) | Missense Mutation (SNP) | VAF 6/50 reads (12%) | PolyPhen probably damaging (0.996); catalogued as rs373657576, COSV100603559; called by muse, mutect2, varscan2
- TUBGCP2 | c.2053C>T p.R685* | Nonsense Mutation (SNP) | VAF 6/88 reads (7%) | catalogued as rs927305498, COSV53302918; called by muse, mutect2
- UBE3A | c.2511A>T p.L837F | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99217000; called by muse, mutect2, varscan2
- UBXN4 | c.1474G>A p.D492N | Missense Mutation (SNP) | VAF 22/125 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99738900; called by muse, mutect2, varscan2
- UGT3A2 | c.301T>A p.L101I | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.324); catalogued as COSV99236170; called by muse, mutect2
- VANGL2 | c.814G>C p.A272P | Missense Mutation (SNP) | VAF 21/125 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100925550; called by muse, mutect2, varscan2
- VNN1 | c.1235G>T p.G412V | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100907702; called by muse, mutect2, varscan2
- VNN2 | c.943C>T p.P315S | Missense Mutation (SNP) | VAF 29/158 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.083); catalogued as COSV100426742; called by muse, mutect2, varscan2
- VPS13B | c.5563G>T p.A1855S | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT tolerated (0.73); PolyPhen benign (0.02); catalogued as COSV100661509; called by muse, mutect2, varscan2
- VRK2 | c.258C>A p.I86= | Splice Region (SNP) | VAF 12/96 reads (13%) | catalogued as COSV100417760; called by muse, mutect2, varscan2
- VWF | c.1399G>A p.D467N | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as COSV99778597; called by muse, mutect2, varscan2
- WDR76 | c.266C>G p.T89S | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV99776236; called by muse, mutect2, varscan2
- WDR91 | c.1333G>T p.A445S | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.452); catalogued as COSV100615634; called by muse, mutect2, varscan2
- WIPF1 | c.1124G>A p.R375Q | Missense Mutation (SNP) | VAF 42/230 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV99768379; called by muse, mutect2, varscan2
- WNT11 | c.946C>G p.R316G | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100490291; called by muse, mutect2, varscan2
- XIRP2 | c.1727T>C p.M576T (on ENST00000628543; = p.M751T on NM_152381.6) | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.051); catalogued as COSV99741046; called by muse, mutect2, varscan2
- ZC4H2 | c.64C>A p.L22M | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.661); catalogued as COSV100564877; called by muse, mutect2, varscan2
- ZFP2 | c.140G>A p.G47E | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1007929077, COSV63725592; called by muse, mutect2, varscan2
- ZFP82 | c.911A>G p.N304S | Missense Mutation (SNP) | VAF 33/196 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs140765560; called by muse, mutect2, varscan2
- ZFYVE26 | c.7465G>C p.A2489P | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100720268; called by muse, mutect2, varscan2
- ZIC4 | c.872C>T p.S291L | Missense Mutation (SNP) | VAF 17/143 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as rs916708888, COSV67172681, COSV67173104; called by muse, mutect2, varscan2
- ZNF207 | c.617C>T p.P206L | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (1); PolyPhen probably damaging (0.998); catalogued as COSV100340431; called by muse, mutect2, varscan2
- ZNF284 | c.311G>C p.W104S | Missense Mutation (SNP) | VAF 4/92 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as COSV101398955; called by muse, mutect2
- ZNF382 | c.669G>T p.M223I | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV99497665; called by muse, mutect2
- ZNF431 | c.310G>C p.E104Q | Missense Mutation (SNP) | VAF 27/138 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as COSV100218611, COSV60676036; called by muse, mutect2, varscan2
- ZNF462 | c.4651G>A p.D1551N | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1257225212, COSV99470479; called by muse, mutect2, varscan2
- ZNF534 | c.787G>T p.V263F (on ENST00000332323 / NM_001143939.3; = p.V250F on NM_001143938.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.759); catalogued as COSV99989602; called by muse, mutect2
- ZNF665 | c.247C>T p.H83Y (on ENST00000600412; = p.H148Y on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/167 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.775); catalogued as COSV101128182; called by muse, mutect2, varscan2
- ZNF701 | c.202G>C p.A68P (on ENST00000301093; = p.A2P on NM_018260.3) | Missense Mutation (SNP) | VAF 10/119 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.985); catalogued as COSV99990630, COSV99990769; called by muse, mutect2
- ZNF711 | c.2042G>T p.C681F | Missense Mutation (SNP) | VAF 5/96 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99340853; called by muse, mutect2
- ZNF746 | c.1289G>T p.R430L | Missense Mutation (SNP) | VAF 7/8 reads (88%) | SIFT tolerated (0.21); PolyPhen benign (0.021); catalogued as rs865939023, COSV100502404; called by muse, mutect2, varscan2
- ZNF804A | c.1240A>T p.K414* | Nonsense Mutation (SNP) | VAF 29/155 reads (19%) | catalogued as COSV100167238; called by muse, mutect2, varscan2
- ZP4 | c.1567G>C p.V523L | Missense Mutation (SNP) | VAF 34/166 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV100850646; called by muse, mutect2, varscan2
- ZSWIM3 | c.647G>A p.R216H | Missense Mutation (SNP) | VAF 25/170 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs779734410, COSV54852918; called by muse, mutect2, varscan2
- C1QTNF4 | c.239dup p.T81Hfs*83 | Frame Shift Ins (INS) | VAF 6/38 reads (16%) | called by pindel, varscan2
- CREBBP | c.2925del p.S976Pfs*22 | Frame Shift Del (DEL) | VAF 20/156 reads (13%) | called by mutect2, pindel, varscan2
- CWC25 | c.108G>T p.K36N | Missense Mutation (SNP) | VAF 43/211 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FCGBP | c.8930A>G p.Q2977R | Missense Mutation (SNP) | VAF 42/518 reads (8%) | SIFT tolerated (0.55); PolyPhen benign (0.046); called by muse, mutect2
- FCRL1 | c.45A>T p.E15D | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- GIGYF1 | c.2647del p.E883Rfs*7 | Frame Shift Del (DEL) | VAF 24/82 reads (29%) | called by mutect2, pindel, varscan2
- HPS3 | c.2822dup p.E942* | Frame Shift Ins (INS) | VAF 32/105 reads (30%) | called by mutect2, pindel, varscan2
- MRC1 | c.2107A>G p.I703V | Missense Mutation (SNP) | VAF 38/177 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PDCL | c.725del p.G242Vfs*3 | Frame Shift Del (DEL) | VAF 23/124 reads (19%) | called by mutect2, pindel, varscan2
- PRAMEF2 | c.1018del p.L340* | Frame Shift Del (DEL) | VAF 106/484 reads (22%) | called by pindel, varscan2
- SEZ6L | c.3072_3074delinsACTC p.*1025Lfs*29 | Frame Shift Ins (INS) | VAF 22/195 reads (11%) | called by pindel, varscan2*
- ABCB4 | c.2793G>C p.V931= | Silent (SNP) | VAF 26/66 reads (39%) | catalogued as COSV55932044, COSV99710087; called by muse, mutect2, varscan2
- ACSM2A | c.1353T>C p.D451= (on ENST00000219054; = p.D372= on NM_001308169.2) | Silent (SNP) | VAF 19/230 reads (8%) | catalogued as COSV99525105; called by muse, mutect2
- ADGRL3 | c.729T>C p.T243= (on ENST00000506720 / NM_001322402.2; = p.T175= on NM_015236.6) | Silent (SNP) | VAF 17/67 reads (25%) | catalogued as COSV101546966; called by muse, mutect2, varscan2
- AFAP1 | c.408A>G p.K136= | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as COSV100631322; called by muse, mutect2, varscan2
- ALPG | c.1491C>A p.P497= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as COSV99779247; called by muse, mutect2, varscan2
- ARGFX | c.477C>A p.P159= | Silent (SNP) | VAF 30/226 reads (13%) | catalogued as COSV100544099; called by muse, mutect2, varscan2
- ASH1L | c.4989C>G p.S1663= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as COSV100853292; called by muse, mutect2, varscan2
- BBX | c.2619A>G p.K873= (on ENST00000325805 / NM_001142568.3; = p.K843= on NM_020235.7) | Silent (SNP) | VAF 50/119 reads (42%) | catalogued as COSV57894764; called by muse, mutect2, varscan2
- BTK | c.360A>T p.L120= | Silent (SNP) | VAF 35/143 reads (24%) | catalogued as COSV100437502; called by muse, mutect2, varscan2
- C2orf78 | c.2685A>G p.K895= | Silent (SNP) | VAF 3/36 reads (8%) | catalogued as COSV101280941; called by muse, mutect2
- CAD | c.3261G>T p.V1087= | Silent (SNP) | VAF 27/147 reads (18%) | catalogued as COSV99254779; called by muse, mutect2, varscan2
- CHSY3 | c.600G>T p.P200= | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as COSV59279302; called by muse, mutect2, varscan2
- COL22A1 | c.2352T>C p.L784= | Silent (SNP) | VAF 56/347 reads (16%) | catalogued as COSV100277499; called by muse, mutect2, varscan2
- DCST1 | c.633T>C p.D211= | Silent (SNP) | VAF 20/105 reads (19%) | catalogued as rs753156259, COSV99792949; called by muse, mutect2, varscan2
- DMD | c.10674C>T p.L3558= | Silent (SNP) | VAF 9/94 reads (10%) | catalogued as COSV100626656; called by muse, mutect2, varscan2
- DNTTIP2 | c.453T>C p.S151= | Silent (SNP) | VAF 26/74 reads (35%) | catalogued as COSV100785154; called by muse, mutect2, varscan2
- DPM1 | c.696G>C p.V232= | Silent (SNP) | VAF 14/88 reads (16%) | catalogued as COSV100857709; called by muse, mutect2, varscan2
- ELMO1 | c.1920C>T p.L640= | Silent (SNP) | VAF 47/264 reads (18%) | catalogued as rs202135895, COSV100163941; called by muse, mutect2, varscan2
- FAM83E | c.873C>G p.L291= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as COSV99572064, COSV99572149; called by muse, mutect2
- FBXO6 | c.84G>A p.V28= | Silent (SNP) | VAF 7/106 reads (7%) | catalogued as rs1378340173, COSV100950995; called by muse, mutect2
- GOLGB1 | c.7008A>T p.G2336= | Silent (SNP) | VAF 13/107 reads (12%) | catalogued as COSV100510591; called by muse, mutect2, varscan2
- GPRC6A | c.2167C>T p.L723= | Silent (SNP) | VAF 11/78 reads (14%) | catalogued as rs373125688; called by muse, mutect2, varscan2
- GPRIN1 | c.1677A>T p.A559= | Silent (SNP) | VAF 32/136 reads (24%) | catalogued as COSV99991343; called by muse, mutect2, varscan2
- HECW1 | c.3378A>T p.P1126= | Silent (SNP) | VAF 21/101 reads (21%) | catalogued as COSV101223184; called by muse, mutect2, varscan2
- HEY1 | c.190C>A p.R64= | Silent (SNP) | VAF 34/147 reads (23%) | catalogued as COSV100559204; called by muse, mutect2, varscan2
- HOXC10 | c.894C>G p.R298= | Silent (SNP) | VAF 18/66 reads (27%) | catalogued as COSV100329056; called by muse, mutect2, varscan2
- IQCE | c.1560C>T p.D520= | Silent (SNP) | VAF 36/110 reads (33%) | catalogued as rs761339664, COSV100383313; called by muse, mutect2, varscan2
- KALRN | c.3630G>A p.R1210= | Silent (SNP) | VAF 24/199 reads (12%) | catalogued as COSV99563271; called by muse, mutect2, varscan2
- KCNJ12 | c.1218C>G p.P406= | Silent (SNP) | VAF 5/47 reads (11%) | catalogued as COSV59166970, COSV59171384; called by muse, mutect2
- KCNQ2 | c.1584G>A p.V528= (on ENST00000359125 / NM_172107.4; = p.V500= on NM_004518.6) | Silent (SNP) | VAF 13/77 reads (17%) | catalogued as COSV100610023; called by muse, mutect2, varscan2
- KCNQ2 | c.996G>A p.R332= | Silent (SNP) | VAF 12/102 reads (12%) | catalogued as COSV100610024; called by muse, mutect2, varscan2
- KIRREL1 | c.1524G>T p.L508= | Silent (SNP) | VAF 18/226 reads (8%) | catalogued as COSV100779657, COSV63286216; called by muse, mutect2
- LAMA1 | c.6810C>G p.G2270= | Silent (SNP) | VAF 28/117 reads (24%) | catalogued as COSV101055770; called by muse, mutect2, varscan2
- LAMB4 | c.4047A>G p.L1349= | Silent (SNP) | VAF 13/42 reads (31%) | catalogued as COSV99223521; called by muse, mutect2, varscan2
- LAMP3 | c.876C>G p.L292= | Silent (SNP) | VAF 44/324 reads (14%) | catalogued as COSV99660455; called by muse, varscan2
- LGALS9B | c.582G>A p.Q194= | Silent (SNP) | VAF 34/209 reads (16%) | catalogued as COSV100162922; called by muse, mutect2, varscan2
- MC5R | c.951C>T p.I317= | Silent (SNP) | VAF 28/129 reads (22%) | catalogued as rs200297627, COSV100228987; called by muse, mutect2, varscan2
- MLXIPL | c.1488C>T p.P496= | Silent (SNP) | VAF 5/11 reads (45%) | catalogued as rs782180374, COSV57669632; called by muse, mutect2, varscan2
- MRC1 | c.852G>T p.L284= | Silent (SNP) | VAF 56/234 reads (24%) | called by muse, mutect2, varscan2
- MUC16 | c.32148T>G p.P10716= | Silent (SNP) | VAF 44/386 reads (11%) | catalogued as COSV101199263; called by muse, mutect2, varscan2
- MUC5B | c.6084C>A p.T2028= | Silent (SNP) | VAF 73/298 reads (24%) | catalogued as COSV101500211; called by muse, varscan2
- MYO7A | c.1071C>A p.S357= | Silent (SNP) | VAF 11/94 reads (12%) | catalogued as rs781971094, COSV101289093, COSV68683668; called by muse, mutect2, varscan2
- NIPAL4 | c.1098G>C p.T366= | Silent (SNP) | VAF 31/117 reads (26%) | catalogued as COSV57430973, COSV99976728; called by muse, mutect2, varscan2
- NLRP13 | c.1347T>A p.T449= | Silent (SNP) | VAF 14/144 reads (10%) | catalogued as COSV100738132; called by muse, mutect2
- NME8 | c.117T>C p.C39= | Silent (SNP) | VAF 17/106 reads (16%) | catalogued as COSV99553065; called by muse, mutect2, varscan2
- OR2M3 | c.159C>A p.T53= | Silent (SNP) | VAF 136/687 reads (20%) | catalogued as COSV101513411; called by muse, mutect2, varscan2
- OR2M3 | c.657T>A p.A219= | Silent (SNP) | VAF 83/453 reads (18%) | catalogued as COSV101513412; called by muse, mutect2, varscan2
- OSGEP | c.900C>G p.A300= | Silent (SNP) | VAF 20/64 reads (31%) | catalogued as COSV99247943; called by muse, mutect2, varscan2
- OVCH1 | c.1995T>C p.I665= | Silent (SNP) | VAF 14/112 reads (13%) | catalogued as COSV100548399; called by muse, mutect2, varscan2
- PEG3 | c.6G>C p.L2= | Silent (SNP) | VAF 12/87 reads (14%) | catalogued as COSV99688228; called by muse, mutect2, varscan2
- PHIP | c.244C>T p.L82= | Silent (SNP) | VAF 15/97 reads (15%) | catalogued as rs770269774, COSV99243756; called by muse, mutect2, varscan2
- PKHD1 | c.8856G>A p.L2952= | Silent (SNP) | VAF 11/126 reads (9%) | catalogued as COSV100582355; called by muse, mutect2
- PLCL1 | c.3192G>T p.L1064= | Silent (SNP) | VAF 17/99 reads (17%) | catalogued as COSV70825463; called by muse, mutect2, varscan2
- PLEC | c.5931C>G p.A1977= (on ENST00000322810 / NM_201380.4; = p.A1867= on NM_000445.5) | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as COSV100512592; called by muse, mutect2
- PLXNC1 | c.2178C>T p.S726= | Silent (SNP) | VAF 26/206 reads (13%) | catalogued as COSV51573711, COSV99312818; called by muse, mutect2, varscan2
- RYR2 | c.5148T>C p.T1716= | Silent (SNP) | VAF 11/59 reads (19%) | catalogued as COSV100769221; called by muse, mutect2, varscan2
- SCAF11 | c.3480C>T p.N1160= | Silent (SNP) | VAF 31/225 reads (14%) | catalogued as rs983611440, COSV101014207; called by muse, mutect2, varscan2
- SHPRH | c.2166T>C p.S722= | Silent (SNP) | VAF 11/96 reads (11%) | catalogued as COSV51615615; called by muse, mutect2, varscan2
- SLC22A9 | c.648T>C p.N216= | Silent (SNP) | VAF 42/242 reads (17%) | catalogued as COSV99654884; called by muse, mutect2, varscan2
- SLC25A37 | c.402C>T p.D134= | Silent (SNP) | VAF 11/69 reads (16%) | catalogued as rs568296478, COSV51563126, COSV51563487; called by muse, mutect2, varscan2
- SLC5A11 | c.1458G>C p.S486= | Silent (SNP) | VAF 8/63 reads (13%) | catalogued as COSV100762730, COSV100762742; called by muse, mutect2, varscan2
- SLC6A17 | c.1281G>A p.L427= | Silent (SNP) | VAF 4/57 reads (7%) | called by muse, mutect2
- SMOC2 | c.615G>A p.Q205= (on ENST00000356284 / NM_001166412.2; = p.Q216= on NM_022138.3) | Silent (SNP) | VAF 17/99 reads (17%) | catalogued as COSV62434292, COSV62437486; called by muse, mutect2, varscan2
- SULT1C3 | c.256A>C p.R86= | Silent (SNP) | VAF 16/86 reads (19%) | catalogued as COSV100227403; called by muse, mutect2, varscan2
- TCF20 | c.3642G>A p.P1214= | Silent (SNP) | VAF 23/129 reads (18%) | catalogued as rs367613861, COSV100166419; called by muse, mutect2, varscan2
- TIE1 | c.1161A>G p.L387= | Silent (SNP) | VAF 32/93 reads (34%) | catalogued as COSV100992043; called by muse, mutect2, varscan2
- TNN | c.2817C>A p.V939= | Silent (SNP) | VAF 31/99 reads (31%) | catalogued as COSV53435655, COSV99511592; called by muse, mutect2, varscan2
- TTN | c.71691T>C p.P23897= (on ENST00000591111; = p.P16473= on NM_003319.4) | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as COSV100603551; called by muse, mutect2, varscan2
- USH2A | c.3558T>C p.C1186= | Silent (SNP) | VAF 27/215 reads (13%) | catalogued as CD071414, COSV100232362, COSV56391679; called by muse, mutect2, varscan2
- VAV1 | c.1842A>G p.G614= | Silent (SNP) | VAF 16/81 reads (20%) | catalogued as COSV100408864; called by muse, mutect2, varscan2
- ZBED8 | c.657G>C p.V219= | Silent (SNP) | VAF 17/79 reads (22%) | catalogued as COSV101283486; called by muse, mutect2, varscan2
- ZEB2 | c.2910A>G p.Q970= | Silent (SNP) | VAF 11/89 reads (12%) | catalogued as COSV100355639; called by muse, mutect2, varscan2
- ZNF804B | c.3801C>A p.P1267= | Silent (SNP) | VAF 20/287 reads (7%) | catalogued as COSV100302883, COSV60847285; called by muse, mutect2
- ADGRB2 | c.-190-1831C>A | Intron (SNP) | VAF 58/168 reads (35%) | catalogued as COSV99925969; called by muse, mutect2, varscan2
- FOLH1B | n.1033del | RNA (DEL) | VAF 14/107 reads (13%) | called by mutect2, varscan2
- FOLH1B | n.1737C>A | RNA (SNP) | VAF 5/80 reads (6%) | catalogued as rs1316471475; called by muse, mutect2
- FOLH1B | n.1738C>A | RNA (SNP) | VAF 5/78 reads (6%) | called by muse, mutect2
- NBPF25P | n.1161A>C | RNA (SNP) | VAF 75/372 reads (20%) | called by muse, mutect2, varscan2
- OR3A4P | n.949C>T | RNA (SNP) | VAF 37/207 reads (18%) | called by muse, mutect2, varscan2
- PKD1L2 | n.2669C>G | RNA (SNP) | VAF 23/81 reads (28%) | called by muse, mutect2, varscan2
- PNPO | c.417+288G>T | Intron (SNP) | VAF 13/73 reads (18%) | catalogued as COSV99846487; called by muse, mutect2, varscan2
- SF1 | c.*374G>T | 3'UTR (SNP) | VAF 53/282 reads (19%) | catalogued as rs746199390, COSV99918151; called by muse, mutect2, varscan2
